Somatic mutation profile of tumor specimen ALCH-B2FS-TTP1-A (aliquot ALCH-B2FS-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2FS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,141 days).
Specimen ALCH-B2FS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36ee8659-0ff6-4b36-9fbb-4d8528d28aef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FS-NB1-A (Blood Derived Normal), aliquot ALCH-B2FS-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8070d240-8213-41d2-9e76-597d2c138177

The open-access MAF lists 387 somatic variants for this specimen: 243 protein-altering or splice-affecting, 101 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 101, Intron 21, Nonsense Mutation 18, Splice Region 8, Frame Shift Del 7, 5'Flank 7, RNA 5, Splice Site 5, 5'UTR 4, 3'UTR 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ACSL1 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1272340296; called by muse, mutect2, varscan2
- ACTRT1 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100947590; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1577-4G>A | Splice Region (SNP) | VAF 25/135 reads (19%) | catalogued as rs369298759; called by muse, mutect2, varscan2
- AGXT2 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 98/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183997; called by mutect2, varscan2
- ANKH | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.102); catalogued as COSV52480395; called by muse, mutect2, varscan2
- ANKRD44 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56549923; called by muse, mutect2, varscan2
- ARHGAP44 | c.1694T>A p.L565Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.085); catalogued as rs1195077205; called by muse, mutect2
- ATRNL1 | c.2882G>A p.C961Y | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100370253, COSV58089644; called by muse, mutect2, varscan2
- BCHE | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52255781; called by muse, mutect2, varscan2
- C10orf71 | c.3878A>G p.Q1293R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1235303615; called by muse, mutect2, varscan2
- C6orf47 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs1383300817, COSV63264008; called by muse, mutect2, varscan2
- CAD | c.6379G>A p.E2127K | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.992); catalogued as COSV99255685; called by muse, mutect2, varscan2
- CALR3 | c.732delinsAG p.N244Kfs*3 | Frame Shift Ins (INS) | VAF 37/338 reads (11%) | catalogued as COSV104372494; called by pindel, varscan2*
- CCDC141 | c.3924G>C p.K1308N | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs910795143, COSV55374778; called by muse, mutect2, varscan2
- CGB1 | c.9+4G>A | Splice Region (SNP) | VAF 52/355 reads (15%) | catalogued as rs754810554; called by muse, mutect2, varscan2
- CKAP5 | c.3578T>C p.I1193T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs1475751415; called by muse, mutect2, varscan2
- CNTNAP2 | c.1494T>A p.F498L | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV62188309; called by muse, mutect2, varscan2
- COL6A2 | c.1019del p.G340Dfs*68 | Frame Shift Del (DEL) | VAF 65/254 reads (26%) | catalogued as COSV56007190; called by mutect2, pindel, varscan2
- COQ8B | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99699370; called by muse, mutect2, varscan2
- CPAMD8 | c.976G>T p.E326* (on ENST00000651564; = p.E279* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 27/158 reads (17%) | catalogued as COSV52232177, COSV99358875; called by muse, mutect2, varscan2
- CSH2 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 114/1161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61080493; called by muse, mutect2
- CTCF | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV50465416; called by muse, mutect2, varscan2
- CTNNA3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV101044631; called by muse, mutect2, varscan2
- CYP2C8 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.03); catalogued as rs1156361410; called by muse, mutect2, varscan2
- DAAM2 | c.1601C>G p.S534* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99227252; called by muse, mutect2, varscan2
- DCTN1 | c.3122C>G p.S1041C | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV62620969; called by muse, mutect2, varscan2
- DCTN3 | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1279777490; called by muse, mutect2, varscan2
- DEGS2 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202019341; called by muse, mutect2, varscan2
- DTNB | c.148+1G>T p.X50_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56482808; called by muse, mutect2, varscan2
- EVX1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.074); catalogued as rs1339165827, COSV56085567; called by muse, mutect2
- FAM193A | c.2403G>T p.G801= | Splice Region (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100219264; called by muse, mutect2, varscan2
- GRIK4 | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757609162, COSV101483420; called by muse, mutect2, varscan2
- HKDC1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 42/308 reads (14%) | catalogued as rs377327285; called by muse, mutect2, varscan2
- HTR3C | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100570614; called by muse, mutect2, varscan2
- ICE1 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.035); catalogued as COSV99030980; called by muse, mutect2, varscan2
- IPO9 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100843576; called by muse, mutect2, varscan2
- IQUB | c.601del p.E201Kfs*15 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as COSV61238225; called by mutect2, pindel, varscan2
- ITGAD | c.2865T>A p.N955K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.332); catalogued as rs750977157; called by muse, mutect2, varscan2
- JAM2 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.623); catalogued as COSV57256698; called by muse, mutect2
- KCNV1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV52090264; called by muse, mutect2, varscan2
- KIAA1549L | c.1954C>A p.P652T (on ENST00000321505; = p.P949T on NM_012194.3) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV99682534; called by muse, mutect2, varscan2
- KRT74 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 93/472 reads (20%) | catalogued as COSV99977405; called by muse, mutect2, varscan2
- LCE3C | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100425273; called by muse, mutect2, varscan2
- MARCHF11 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100197580, COSV60131250; called by muse, mutect2, varscan2
- MC5R | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV100229116; called by muse, mutect2, varscan2
- MCOLN1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs886054695, COSV51176962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MGA | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748756129, COSV54951327; called by muse, mutect2, varscan2
- MMP26 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.564); catalogued as rs771890155; called by muse, mutect2, varscan2
- NCAM2 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 68/500 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.618); catalogued as COSV53059400; called by muse, varscan2
- NEFH | c.1199C>A p.A400D | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100151563; called by muse, mutect2, varscan2
- NLGN1 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs200936288; called by muse, mutect2, varscan2
- NNMT | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs142397660; called by muse, mutect2, varscan2
- NOBOX | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1203231695; called by muse, mutect2, varscan2
- NTRK2 | c.1435A>T p.S479C (on ENST00000323115 / NM_001369534.1; = p.S495C on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52852824; called by muse, mutect2, varscan2
- OGDHL | c.2477A>C p.H826P | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65101737; called by muse, mutect2, varscan2
- OR4C11 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs772341211, COSV56354418; called by muse, mutect2, varscan2
- OR4C6 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as rs201388016, COSV58602812, COSV58605283; called by muse, mutect2, varscan2
- OR51F2 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59064505; called by muse, mutect2, varscan2
- OR5H1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 71/514 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100641791; called by muse, mutect2, varscan2
- OR5L1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368833257, COSV61733704; called by muse, varscan2
- OR5L1 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733853, COSV61734285; called by muse, varscan2
- OR8J1 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV57318655; called by muse, mutect2, varscan2
- PCDH8 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58810775; called by muse, mutect2, varscan2
- PCDHB7 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 111/594 reads (19%) | catalogued as COSV50777957; called by muse, mutect2, varscan2
- PCNT | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764560918, COSV64031212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZRN3 | c.2156G>T p.W719L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55216717; called by muse, mutect2, varscan2
- PLAU | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65641119; called by muse, mutect2, varscan2
- PLCXD3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs182360912, COSV60606280; called by muse, mutect2, varscan2
- PLEKHH3 | c.1100C>G p.S367W | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1159062419, COSV52218433; called by muse, mutect2, varscan2
- PPWD1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs147434634; called by muse, mutect2, varscan2
- PRB3 | c.842del p.P281Hfs*68 (on ENST00000381842; = p.P323Hfs*? on NM_006249.5) | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as COSV54388902; called by mutect2, pindel, varscan2
- PTPRT | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 23/139 reads (17%) | catalogued as rs752116362, COSV99049483; called by muse, mutect2, varscan2
- RET | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 76/441 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV60694867; called by muse, mutect2, varscan2
- RNF114 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.076); catalogued as rs759804307; called by muse, mutect2, varscan2
- SCARF2 | c.1321A>C p.K441Q | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.651); catalogued as rs1569108103; called by muse, mutect2, varscan2
- SEMA4A | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757839207; called by muse, mutect2, varscan2
- SI | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV52268542; called by muse, mutect2
- SLC13A4 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs1363435870; called by muse, mutect2, varscan2
- SLC18A2 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1565004202; called by muse, mutect2, varscan2
- SLC18A3 | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1237667584; called by muse, mutect2, varscan2
- SLC9A4 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs764521439, COSV54838348; called by muse, mutect2, varscan2
- SMC3 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs765889443; called by muse, mutect2, varscan2
- SOX30 | c.1844C>A p.P615H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99398575; called by muse, mutect2
- SP140 | c.2016+1G>A p.X672_splice | Splice Site (SNP) | VAF 12/81 reads (15%) | catalogued as rs1433258682; called by muse, mutect2, varscan2
- SYNE1 | c.22520G>A p.R7507H (on ENST00000367255 / NM_182961.4; = p.R7436H on NM_033071.3) | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776733924, COSV55059207; called by muse, varscan2
- SZT2 | c.8670del p.T2891Qfs*19 (on ENST00000634258 / NM_001365999.1; = p.T2834Qfs*19 on NM_015284.4) | Frame Shift Del (DEL) | VAF 106/302 reads (35%) | catalogued as COSV65167851; called by mutect2, pindel, varscan2
- TBC1D10C | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV56701883; called by muse, mutect2, varscan2
- TBC1D9 | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.441); catalogued as rs754810759; called by muse, mutect2, varscan2
- TECRL | c.344T>C p.L115S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67090558; called by muse, mutect2, varscan2
- TNFRSF11A | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV54023652; called by muse, mutect2, varscan2
- UNC5D | c.2609C>G p.A870G | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV54767142, COSV54782209; called by muse, varscan2
- VAMP7 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.078); catalogued as rs772345066; called by muse, mutect2, varscan2
- WDR26 | c.1166A>T p.Y389F (on ENST00000414423 / NM_001379403.1; = p.Y289F on NM_025160.7) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV54357179; called by muse, mutect2
- XKR3 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV58887379; called by muse, mutect2, varscan2
- ZAN | c.5634G>T p.P1878= | Splice Region (SNP) | VAF 14/61 reads (23%) | catalogued as rs779344893; called by muse, mutect2
- ZFHX4 | c.7750G>A p.D2584N | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs774272950, COSV50639548; called by muse, mutect2, varscan2
- ZNRF4 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs769670197, COSV55775771; called by muse, mutect2, varscan2
- ZP3 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV60635119; called by muse, mutect2, varscan2
- ABCA4 | c.1809C>A p.Y603* | Nonsense Mutation (SNP) | VAF 122/417 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2296A>G p.K766E | Missense Mutation (SNP) | VAF 143/511 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- AKAP3 | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ALK | c.3827A>C p.D1276A | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AMER2 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- APOB | c.2362A>T p.S788C | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ARHGEF11 | c.2483T>A p.V828E | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ASIC5 | c.628T>A p.F210I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP10A | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1310C>A p.A437E | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- B4GALNT1 | c.712+7G>C | Splice Region (SNP) | VAF 107/579 reads (18%) | called by muse, mutect2, varscan2
- C12orf40 | c.1891C>T p.L631F | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, varscan2
- CAPRIN2 | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- CASP8AP2 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC120 | c.832del p.R278Gfs*75 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CCDC141 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- CCDC141 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CCDC27 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CCDC63 | c.682A>T p.M228L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC8 | c.243_244del p.R81Sfs*66 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- CENPV | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- CEP135 | c.2538A>C p.Q846H | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, varscan2
- CHM | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.1628G>T p.S543I | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- COL13A1 | c.1037C>G p.P346R (on ENST00000398978 / NM_001130103.2; = p.P289R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CPSF6 | c.1264A>G p.R422G | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CSMD1 | c.356C>A p.T119N | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CWC22 | c.2725T>C p.*909Qext*6 | Nonstop Mutation (SNP) | VAF 7/49 reads (14%) | called by muse, varscan2
- CYTH4 | c.696+2T>A p.X232_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | called by muse, varscan2
- DCAF4L2 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 166/631 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DLGAP2 | c.2779C>A p.L927I | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH8 | c.12886G>C p.A4296P | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DPP10 | c.1657A>C p.K553Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, varscan2
- DSG3 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2B4 | c.705+8C>T | Splice Region (SNP) | VAF 62/287 reads (22%) | called by muse, mutect2, varscan2
- ENPEP | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA10 | c.2878G>T p.G960W | Missense Mutation (SNP) | VAF 116/309 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERV3-1 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- FAM83C | c.903C>A p.Y301* | Nonsense Mutation (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- FBXL5 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- FGF19 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 52/1670 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- FLNC | c.7562-1G>A p.X2521_splice | Splice Site (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- FNDC1 | c.2468A>T p.K823I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- FRG2C | c.832A>T p.K278* | Nonsense Mutation (SNP) | VAF 19/374 reads (5%) | called by muse, mutect2
- FSCB | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- GLDN | c.215T>A p.L72* | Nonsense Mutation (SNP) | VAF 98/367 reads (27%) | called by muse, mutect2, varscan2
- GMIP | c.1510A>G p.K504E | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPD1L | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- GPR146 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HKDC1 | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HPN | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IFNA17 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- IGHV2OR16-5 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by mutect2, varscan2
- IGKV2-24 | c.153C>A p.H51Q | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGLV2-8 | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 98/522 reads (19%) | called by muse, mutect2, varscan2
- IL2RB | c.1656G>T p.*552Yext*87 | Nonstop Mutation (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- JPH2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- KANK4 | c.1044G>T p.Q348H | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KAZN | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 162/436 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KCNB1 | c.1983G>A p.M661I | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH2 | c.198C>G p.C66W | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD3 | c.1354T>A p.F452I | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM2A | c.939C>G p.N313K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KERA | c.696T>A p.Y232* | Nonsense Mutation (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- KIAA1109 | c.9151C>T p.P3051S | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- L3HYPDH | c.630G>C p.R210S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LAMB1 | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- LAMC3 | c.2809A>G p.T937A | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LGALS13 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 82/561 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRB4 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LPA | c.4321G>A p.D1441N | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- LRP5 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP5 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LZTR1 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K14 | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 709/1523 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MAP3K15 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MAPK7 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF11 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRPL45 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MRTFB | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTRR | c.437G>T p.G146V (on ENST00000264668; = p.G119V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/572 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.12580T>A p.L4194M | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NCAM1 | c.1376A>G p.N459S (on ENST00000316851 / NM_181351.5; = p.N449S on NM_000615.7) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NDUFV1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 70/452 reads (15%) | called by muse, mutect2, varscan2
- NEMF | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 40/197 reads (20%) | called by muse, mutect2, varscan2
- NFASC | c.119C>A p.P40Q (on ENST00000339876 / NM_001378329.1; = p.P34Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPHS1 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRG3 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRK | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NWD2 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- OGDHL | c.1993G>T p.V665L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2A14 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR6F1 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 72/385 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- OSMR | c.351G>T p.L117F | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PARD3B | c.2515G>T p.E839* (on ENST00000406610 / NM_001302769.2; = p.E770* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 55/271 reads (20%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.566_572del p.S189Tfs*10 | Frame Shift Del (DEL) | VAF 31/172 reads (18%) | called by mutect2, pindel, varscan2
- PCLO | c.7300A>G p.K2434E | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PDHA2 | c.362T>G p.V121G | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PHKA2 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PKN1 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2
- PLG | c.1177A>G p.T393A | Missense Mutation (SNP) | VAF 77/352 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PPFIA4 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPP1R12B | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- PRDM5 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PREX2 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RETREG3 | c.505-7_505-3del | Splice Region (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- RHOBTB1 | c.1781A>T p.D594V | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.394); called by muse, varscan2
- RNF152 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RYR2 | c.3020G>T p.W1007L | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RYR2 | c.6322A>G p.I2108V | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SAMD9L | c.2234G>T p.C745F | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SBSN | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, varscan2
- SEC16A | c.3760G>T p.D1254Y | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINA3 | c.1178T>G p.V393G | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SIRPD | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SLC17A6 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC1A3 | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, varscan2
- SLC5A3 | c.1202G>C p.S401T | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC5A4 | c.1020A>T p.T340= | Splice Region (SNP) | VAF 16/88 reads (18%) | called by muse, varscan2
- SORCS1 | c.831G>C p.L277F | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ST18 | c.1406G>C p.S469T | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- STAB2 | c.2888A>G p.K963R | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- STARD3NL | c.346dup p.A116Gfs*52 | Frame Shift Ins (INS) | VAF 34/367 reads (9%) | called by pindel, varscan2
- STXBP1 | c.1483G>C p.D495H | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAS2R39 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TLE3 | c.1536G>A p.W512* | Nonsense Mutation (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- TMEM171 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.2); called by muse, varscan2
- TRAPPC3 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TRIP10 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC1 | c.499G>T p.A167S (on ENST00000476941 / NM_001251845.2; = p.A133S on NM_003304.4) | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP47 | c.3400G>C p.E1134Q (on ENST00000399455 / NM_001372095.1; = p.E1046Q on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- WASHC4 | c.2157C>G p.F719L | Missense Mutation (SNP) | VAF 19/603 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2
- WDR83OS | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZCCHC18 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8705C>A p.S2902Y | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFR | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZIM3 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF283 | c.1744T>G p.W582G | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ZNF320 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF354B | c.1438G>C p.A480P | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF586 | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF664 | c.645C>A p.C215* | Nonsense Mutation (SNP) | VAF 81/777 reads (10%) | called by muse, mutect2, varscan2
- ZNF735 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF804A | c.1771C>A p.H591N | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ACCSL | c.255G>A p.G85= | Silent (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- AHSG | c.417C>A p.A139= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs753939665; called by muse, mutect2, varscan2
- AMER1 | c.1602G>A p.E534= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs765229185; called by muse, mutect2, varscan2
- ANK3 | c.10047T>G p.A3349= | Silent (SNP) | VAF 54/335 reads (16%) | called by muse, mutect2, varscan2
- AOX1 | c.1068G>C p.G356= | Silent (SNP) | VAF 26/143 reads (18%) | called by muse, mutect2, varscan2
- APC2 | c.5016A>T p.A1672= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.1581C>G p.R527= | Silent (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- ATP8B2 | c.3558G>T p.A1186= (on ENST00000672630; = p.A1153= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 71/339 reads (21%) | catalogued as rs557794271, COSV63833873; called by muse, mutect2, varscan2
- CA6 | c.366C>T p.S122= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV101077558; called by muse, mutect2, varscan2
- CDH20 | c.408C>A p.A136= | Silent (SNP) | VAF 39/185 reads (21%) | called by muse, mutect2, varscan2
- CELF3 | c.204G>C p.L68= | Silent (SNP) | VAF 64/271 reads (24%) | called by muse, mutect2, varscan2
- COQ8B | c.966G>T p.L322= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as COSV99699617; called by muse, mutect2, varscan2
- CPEB4 | c.786A>T p.T262= | Silent (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1122C>A p.R374= | Silent (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- CTNND2 | c.1428C>T p.H476= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs771436418, COSV100478984, COSV58922136; called by muse, mutect2, varscan2
- CYP2D6 | c.1221C>A p.A407= | Silent (SNP) | VAF 63/583 reads (11%) | catalogued as rs1331514126; called by muse, mutect2, varscan2
- DEFB118 | c.138T>C p.D46= | Silent (SNP) | VAF 52/266 reads (20%) | called by muse, mutect2, varscan2
- DLL4 | c.1707C>T p.N569= | Silent (SNP) | VAF 24/282 reads (9%) | catalogued as rs778485828, COSV51062547, COSV51072974; called by muse, mutect2
- DNMT3A | c.1134C>T p.S378= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- ERBIN | c.3771T>C p.N1257= (on ENST00000284037 / NM_001253697.2; = p.N1216= on NM_018695.4) | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as rs1273986298; called by muse, mutect2, varscan2
- FAM135B | c.1590A>G p.P530= | Silent (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- FER1L5 | c.3021C>T p.G1007= (on ENST00000623019; = p.G1014= on NM_001293083.2) | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- FER1L6 | c.3426T>C p.P1142= | Silent (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- FGF4 | c.327G>A p.A109= | Silent (SNP) | VAF 62/1810 reads (3%) | called by muse, mutect2
- GMPPA | c.426T>C p.T142= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs769695080; called by muse, mutect2, varscan2
- GPAM | c.714G>T p.L238= | Silent (SNP) | VAF 53/367 reads (14%) | called by muse, mutect2, varscan2
- H1-8 | c.426C>G p.P142= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV60974683; called by muse, mutect2, varscan2
- HCN1 | c.138C>T p.G46= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1186824624; called by muse, mutect2
- HCN3 | c.957T>C p.P319= | Silent (SNP) | VAF 50/285 reads (18%) | catalogued as COSV100855807; called by muse, mutect2, varscan2
- HOXD1 | c.105G>T p.V35= | Silent (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
- IGSF3 | c.3576C>G p.A1192= (on ENST00000369486 / NM_001007237.3; = p.A1212= on NM_001542.4) | Silent (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- IL17A | c.160C>A p.R54= | Silent (SNP) | VAF 90/538 reads (17%) | catalogued as rs754178712, COSV60684281; called by muse, mutect2, varscan2
- JAKMIP1 | c.1797A>G p.L599= | Silent (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- JAM2 | c.276C>T p.F92= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV57256600; called by muse, mutect2, varscan2
- KARS1 | c.6G>A p.A2= | Silent (SNP) | VAF 91/353 reads (26%) | catalogued as rs768389157; called by muse, mutect2, varscan2
- KATNB1 | c.1623G>C p.L541= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101109106, COSV65553226; called by muse, mutect2
- KCNN4 | c.414G>T p.P138= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- KLF2 | c.612G>A p.A204= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- KLRF1 | c.654T>G p.S218= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- KRTAP10-9 | c.414G>T p.P138= | Silent (SNP) | VAF 130/371 reads (35%) | catalogued as COSV59963242; called by muse, mutect2, varscan2
- LAMA3 | c.8562A>T p.I2854= (on ENST00000313654 / NM_198129.4; = p.I1245= on NM_000227.6) | Silent (SNP) | VAF 55/310 reads (18%) | called by muse, mutect2, varscan2
- LRP1B | c.9702C>G p.T3234= | Silent (SNP) | VAF 31/263 reads (12%) | called by muse, mutect2, varscan2
- LRRC58 | c.444G>C p.L148= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- LY6E | c.357G>C p.L119= | Silent (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2
- MARCHF10 | c.519G>A p.P173= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs751581348; called by muse, mutect2, varscan2
- MYO9B | c.3333A>G p.L1111= | Silent (SNP) | VAF 59/292 reads (20%) | called by muse, mutect2, varscan2
- NECTIN4 | c.1254G>C p.L418= | Silent (SNP) | VAF 33/217 reads (15%) | catalogued as COSV63512713, COSV63512832; called by muse, mutect2, varscan2
- NEURL1 | c.615C>T p.D205= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs766628083; called by muse, mutect2, varscan2
- NGEF | c.768C>G p.P256= | Silent (SNP) | VAF 34/193 reads (18%) | catalogued as COSV50968076; called by muse, mutect2, varscan2
- NIPSNAP2 | c.282A>G p.Q94= | Silent (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- NOTCH2 | c.4716G>T p.L1572= | Silent (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- NPSR1 | c.1035T>C p.R345= | Silent (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- NPTX2 | c.561G>T p.L187= | Silent (SNP) | VAF 76/432 reads (18%) | called by muse, mutect2, varscan2
- NRG3 | c.2037A>G p.V679= (on ENST00000404547 / NM_001370084.1; = p.V655= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/305 reads (14%) | called by muse, mutect2, varscan2
- NUBP1 | c.747C>T p.T249= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs749583634; called by muse, mutect2, varscan2
- NXPE4 | c.282C>A p.T94= | Silent (SNP) | VAF 50/267 reads (19%) | called by muse, mutect2, varscan2
- OR10K1 | c.693C>T p.S231= | Silent (SNP) | VAF 60/393 reads (15%) | catalogued as rs763300748, COSV56871477; called by muse, mutect2, varscan2
- OR2G2 | c.42T>A p.G14= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2
- OR2T11 | c.819C>A p.A273= | Silent (SNP) | VAF 59/361 reads (16%) | called by muse, mutect2, varscan2
- OR4A47 | c.37T>C p.L13= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- OR51F2 | c.45C>A p.L15= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- OR52N5 | c.273C>A p.L91= | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as COSV57698675; called by muse, mutect2, varscan2
- OSBPL6 | c.2106G>T p.G702= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- PFAS | c.3201C>T p.I1067= | Silent (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- PILRB | c.480G>A p.R160= | Silent (SNP) | VAF 41/229 reads (18%) | catalogued as rs746040441; called by muse, mutect2, varscan2
- PLCH2 | c.876A>G p.P292= | Silent (SNP) | VAF 80/201 reads (40%) | catalogued as rs1476103078; called by muse, mutect2, varscan2
- PLEKHA4 | c.1680G>T p.P560= | Silent (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- PLTP | c.1095C>T p.S365= | Silent (SNP) | VAF 61/381 reads (16%) | called by muse, mutect2, varscan2
- PLXNA4 | c.3939G>A p.P1313= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as rs377241563; called by muse, mutect2, varscan2
- PNLIPRP2 | c.42A>C p.T14= | Silent (SNP) | VAF 80/522 reads (15%) | called by muse, varscan2
- POTEJ | c.888T>A p.S296= | Silent (SNP) | VAF 18/147 reads (12%) | called by mutect2, varscan2
- POU3F2 | c.801G>T p.S267= | Silent (SNP) | VAF 48/311 reads (15%) | catalogued as rs764851446; called by muse, mutect2, varscan2
- PRRT3 | c.1905G>C p.P635= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs764472496; called by muse, mutect2, varscan2
- PTPRD | c.2967A>T p.T989= | Silent (SNP) | VAF 37/229 reads (16%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.2214T>C p.C738= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- RBL2 | c.831G>A p.E277= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- RFX6 | c.2733C>G p.S911= | Silent (SNP) | VAF 65/299 reads (22%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2793C>A p.L931= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV55466370; called by muse, mutect2, varscan2
- RNF138 | c.168A>G p.L56= | Silent (SNP) | VAF 51/288 reads (18%) | catalogued as rs965380413; called by muse, mutect2, varscan2
- RYR2 | c.6115C>T p.L2039= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV63698922; called by muse, mutect2, varscan2
- SETD1B | c.2766G>A p.P922= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs369609061; called by muse, mutect2, varscan2
- SLC18A3 | c.1416G>T p.V472= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs1336034969; called by muse, mutect2, varscan2
- SLC27A5 | c.756C>T p.L252= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV54021995; called by muse, mutect2, varscan2
- SLC5A11 | c.1599C>A p.L533= | Silent (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- SLC6A19 | c.532C>A p.R178= | Silent (SNP) | VAF 149/513 reads (29%) | catalogued as CM085707, COSV58669351; called by muse, mutect2, varscan2
- SLC6A19 | c.1713C>A p.P571= | Silent (SNP) | VAF 138/459 reads (30%) | called by muse, mutect2, varscan2
- SOBP | c.2541G>T p.S847= | Silent (SNP) | VAF 80/418 reads (19%) | catalogued as COSV104396857; called by muse, mutect2, varscan2
- TACR2 | c.141C>A p.A47= | Silent (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- TBX22 | c.1377C>A p.I459= | Silent (SNP) | VAF 95/297 reads (32%) | catalogued as rs1436380382, COSV100960609; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMCC1 | c.1278C>T p.A426= (on ENST00000393238 / NM_001349268.2; = p.A102= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- TNFRSF19 | c.408G>T p.V136= | Silent (SNP) | VAF 45/313 reads (14%) | called by muse, mutect2, varscan2
- TNS1 | c.4488G>A p.A1496= | Silent (SNP) | VAF 49/239 reads (21%) | catalogued as rs754402833; called by muse, mutect2, varscan2
- TPP2 | c.3279A>G p.A1093= | Silent (SNP) | VAF 36/199 reads (18%) | called by muse, mutect2, varscan2
- TRIM50 | c.661C>A p.R221= | Silent (SNP) | VAF 42/281 reads (15%) | called by muse, mutect2, varscan2
- TRIM58 | c.267G>T p.A89= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.82989T>C p.A27663= (on ENST00000591111; = p.A20239= on NM_003319.4) | Silent (SNP) | VAF 98/583 reads (17%) | called by muse, mutect2, varscan2
- VRTN | c.1695G>A p.L565= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- XIRP2 | c.1438C>A p.R480= (on ENST00000628543; = p.R655= on NM_152381.6) | Silent (SNP) | VAF 35/189 reads (19%) | called by muse, mutect2, varscan2
- ZIM3 | c.1335A>G p.K445= | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as rs757166670; called by muse, mutect2, varscan2
- ZNF257 | c.705A>G p.G235= | Silent (SNP) | VAF 41/236 reads (17%) | catalogued as rs373144319; called by muse, mutect2, varscan2
- ZNF536 | c.3678C>G p.S1226= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs768334182, COSV62823128; called by muse, mutect2, varscan2
- AC136759.1 | n.506C>A | RNA (SNP) | VAF 42/286 reads (15%) | called by muse, mutect2, varscan2
- ACTR3B | c.-49C>T | 5'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- ADAMTSL4 | chr1:150561219 G>T | 3'Flank (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- ADCY1 | c.1605+2135C>T | Intron (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084992 A>G | 5'Flank (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- AL353804.4 | chrX:73822871 C>T | 5'Flank (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822872 A>G | 5'Flank (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ALKBH3 | c.460-4231C>G | Intron (SNP) | VAF 51/233 reads (22%) | called by muse, mutect2, varscan2
- ANKRD6 | c.1612+42G>C | Intron (SNP) | VAF 104/516 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916304 G>T | 5'Flank (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-109+55G>T | Intron (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- BBS7 | c.*26G>C | 3'UTR (SNP) | VAF 40/192 reads (21%) | called by muse, varscan2
- BEND6 | chr6:56954533 G>A | 5'Flank (SNP) | VAF 75/311 reads (24%) | called by muse, mutect2, varscan2
- CES4A | c.1445-11T>C | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- CHRNA4 | c.228+19A>T | Intron (SNP) | VAF 38/188 reads (20%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240129988 C>A | 3'Flank (SNP) | VAF 38/267 reads (14%) | called by muse, mutect2, varscan2
- CXCL12 | c.267-2615C>G | Intron (SNP) | VAF 69/422 reads (16%) | called by muse, mutect2, varscan2
- FAM90A20P | n.614G>T | RNA (SNP) | VAF 176/562 reads (31%) | catalogued as rs1354461988; called by muse, varscan2
- FAM90A20P | n.904C>T | RNA (SNP) | VAF 256/699 reads (37%) | catalogued as rs539254108; called by muse, mutect2, varscan2
- GK | c.-52G>T | 5'UTR (SNP) | VAF 51/119 reads (43%) | catalogued as COSV100970605; called by muse, mutect2, varscan2
- KCNAB1 | c.276-147944del | Intron (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- LAMA1 | c.7627-38G>C | Intron (SNP) | VAF 54/316 reads (17%) | called by muse, mutect2, varscan2
- LINC02108 | n.155A>T | RNA (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85567G>T | Intron (SNP) | VAF 48/206 reads (23%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40563551 C>A | 5'Flank (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- NRG3 | c.823+1770C>A | Intron (SNP) | VAF 41/209 reads (20%) | called by muse, mutect2, varscan2
- OLAH | c.164-4788G>A | Intron (SNP) | VAF 34/190 reads (18%) | catalogued as rs374137996; called by muse, mutect2, varscan2
- OR2W5 | n.1047C>G | RNA (SNP) | VAF 65/302 reads (22%) | called by muse, mutect2, varscan2
- PAX6 | c.10+34T>C | Intron (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.49+23T>C | Intron (SNP) | VAF 81/544 reads (15%) | called by muse, varscan2
- POU2F1 | c.-8-3185G>T | Intron (SNP) | VAF 45/208 reads (22%) | called by muse, mutect2, varscan2
- PRSS56 | c.-40G>T | 5'UTR (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- PSG1 | c.1243+11C>T | Intron (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- PTPN12 | c.*12A>G | 3'UTR (SNP) | VAF 23/120 reads (19%) | catalogued as rs978882834; called by muse, mutect2, varscan2
- RGS3 | c.3081-111A>G | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+970C>G | Intron (SNP) | VAF 54/279 reads (19%) | catalogued as rs1320636067; called by muse, mutect2, varscan2
- SLC19A1 | c.*555G>T | 3'UTR (SNP) | VAF 100/350 reads (29%) | called by muse, varscan2
- SLC1A3 | c.-24G>C | 5'UTR (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- SLC46A1 | c.1081+88C>A | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51546C>A | Intron (SNP) | VAF 21/107 reads (20%) | catalogued as rs758196707, COSV101043796, COSV67442715; called by muse, mutect2, varscan2
- UQCRB | c.*1277del | 3'UTR (DEL) | VAF 71/393 reads (18%) | called by pindel, varscan2
- WDR76 | chr15:43826988 G>T | 5'Flank (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+44493G>C | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
